Gene-level copy-number profile of tumor specimen TCGA-08-0380-01A from TCGA case TCGA-08-0380, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.7 years (27,277 days).
Specimen TCGA-08-0380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.287eaf79-4e11-4c71-b102-2003017af7dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-08-0380-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95c54f77-0a7b-4d69-8283-ac060d23b7a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,476; copy number 2: 52,417; copy number 3: 4,675; copy number 4: 163; copy number 5: 16; copy number 6: 61; copy number 14: 5; copy number 16: 4; copy number 18: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0380-01): tumor purity 0.33, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,984,765–110,074,641, 3 genes, copy number 18 (within-gene range 2–18): AHCYL1, STRIP1, AL160006.1.
- chr1:115,270,767–115,368,072, 4 genes, copy number 16: AL049825.1, NGF-AS1, NGF, AL512638.3.
- chr7:88,219,359–90,211,635, 16 genes, copy number 5 (within-gene range 3–5): AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1.
- chr11:8,011,278–8,106,243, 5 genes, copy number 14 (within-gene range 2–14): CASC23, TUB, AC116456.1, TUB-AS1, AC116456.2.
- chr11:48,880,111–48,951,895, 5 genes, copy number 6: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP.
- chr12:57,253,762–58,395,138, 56 genes, copy number 6 (within-gene range 2–6): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.

Autosomal genes at a single copy (total copy number 1): 2,476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
